Gene-level copy-number profile of tumor specimen TCGA-29-2434-01A from TCGA case TCGA-29-2434, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.0 years (18,997 days).
Specimen TCGA-29-2434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.05b48ec8-6422-490b-b587-c376cb7d0475.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-2434-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b74b334e-1106-4a02-924c-06992ee41d86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,448; copy number 2: 20,580; copy number 3: 19,492; copy number 4: 10,781; copy number 5: 2,953; copy number 6: 1,666; copy number 7: 856; copy number 8: 455; copy number 9: 379; copy number 10: 160; copy number 11: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-2434-01A-01D-1043-01): tumor purity 0.92, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,248 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,468,496–164,899,296, 14 genes, copy number 5: RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA.
- chr1:231,162,112–232,897,660, 31 genes, copy number 5–6 (within-gene range 4–6): TRIM67, TRIM67-AS1, C1orf131, GNPAT, RNA5SP80, EXOC8, SPRTN, AL117352.1, EGLN1, AL445524.2, SNRPD2P2, AL445524.1, TSNAX, TSNAX-DISC1, LINC00582, DISC1, RNU5A-5P, AL136171.2, AL136171.1, DISC1-IT1, AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2, RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2.
- chr2:32,825,359–32,946,149, 3 genes, copy number 5: LINC00486, LINC00486, Y_RNA.
- chr2:66,820,684–67,412,089, 9 genes, copy number 6: DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1.
- chr2:159,771,851–169,031,324, 97 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:11,745–858,091, 12 genes, copy number 5: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1.
- chr3:9,192,493–23,641,592, 241 genes, copy number 5–8 (broad region; genes not listed).
- chr3:26,015,669–46,027,487, 344 genes, copy number 5 (broad region; genes not listed).
- chr3:117,544,205–117,997,592, 5 genes, copy number 6: RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:129,430,947–143,060,725, 251 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:148,695,994–149,226,334, 16 genes, copy number 5: RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2.
- chr3:157,259,742–198,222,513, 715 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:62,248,294–62,510,771, 5 genes, copy number 5: RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11.
- chr5:13,690,331–34,244,796, 271 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr5:149,345,430–151,303,766, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:75,237,675–78,946,440, 38 genes, copy number 6–7: COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P, RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1.
- chr6:138,725,211–138,793,319, 2 genes, copy number 6 (within-gene range 3–6): CCDC28A-AS1, CCDC28A.
- chr6:159,760,258–160,113,507, 11 genes, copy number 6 (within-gene range 2–6): SOD2-OT1, ACAT2, TCP1, SNORA20, SNORA29, MRPL18, PNLDC1, AL035691.1, MAS1, IGF2R, AIRN.
- chr7:16,461,481–17,680,659, 25 genes, copy number 5–6 (within-gene range 4–6): SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr7:30,496,621–36,841,373, 115 genes, copy number 5–6 (broad region; genes not listed).
- chr7:36,919,357–37,013,630, 2 genes, copy number 6: MIR1200, ELMO1-AS1.
- chr7:46,634,614–48,108,736, 20 genes, copy number 5: HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1.
- chr7:75,996,338–159,233,377, 1,583 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:54,191,582–69,660,915, 225 genes, copy number 5–8 (broad region; genes not listed).
- chr8:69,700,224–69,719,722, 2 genes, copy number 7 (within-gene range 4–7): RN7SKP29, AC091047.1.
- chr8:135,457,456–139,508,971, 20 genes, copy number 5 (within-gene range 4–5): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1.
- chr11:31,509,755–32,794,658, 26 genes, copy number 5 (within-gene range 3–5): ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1.
- chr12:66,767–11,895,377, 442 genes, copy number 6–7 (broad region; genes not listed).
- chr12:38,532,895–47,706,030, 131 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:50,763,710–50,970,506, 11 genes, copy number 5 (within-gene range 3–5): ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3.
- chr12:117,208,142–117,452,170, 2 genes, copy number 6 (within-gene range 3–6): NOS1, ELOCP32.
- chr13:28,820,348–29,595,688, 6 genes, copy number 5 (within-gene range 3–5): MTUS2, MTUS2-AS2, GAPDHP69, AL596092.1, MTUS2-AS1, SLC7A1.
- chr13:97,675,011–110,917,827, 187 genes, copy number 5–6 (broad region; genes not listed).
- chr14:101,948,347–106,875,071, 335 genes, copy number 5 (broad region; genes not listed).
- chr16:46,469,341–51,525,157, 135 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr18:20,946,906–24,162,211, 72 genes, copy number 5 (broad region; genes not listed).
- chr18:24,170,505–24,218,404, 3 genes, copy number 5: RNA5SP452, Metazoa_SRP, RNU6-435P.
- chr19:10,780,254–20,424,969, 554 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:24,445,391–25,390,835, 26 genes, copy number 5: GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2.
- chr20:58,515,379–64,242,253, 195 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,933. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
